Somatic mutation profile of tumor specimen TCGA-CA-6715-01A (aliquot TCGA-CA-6715-01A-21D-1835-10) from TCGA case TCGA-CA-6715, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 63.2 years (23,075 days).
Specimen TCGA-CA-6715-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dc733e12-8edf-49bd-8f45-1fb20dbc2689.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CA-6715-10A (Blood Derived Normal), aliquot TCGA-CA-6715-10A-01D-1835-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2a784549-772c-4507-8798-35ed43013eea

The open-access MAF lists 88 somatic variants for this specimen: 68 protein-altering or splice-affecting, 18 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 18, Splice Site 4, Nonsense Mutation 4, Intron 2, Frame Shift Del 2, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 39/49 reads (80%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs587778720, CM004906, CM022474, COSV52665093, COSV52668963, COSV52693072; ClinVar: drug response / pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCC9 | c.1550G>C p.S517T | Missense Mutation (SNP) | VAF 51/122 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.102); catalogued as COSV99686944; called by muse, mutect2, varscan2
- AC011462.1 | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV100641052; called by muse, mutect2, varscan2
- ACSM2A | c.467C>A p.A156D (on ENST00000219054; = p.A77D on NM_001308169.2) | Missense Mutation (SNP) | VAF 47/136 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV99525651; called by muse, mutect2, varscan2
- ACTR3B | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.182); catalogued as rs777288190, COSV99754445; called by muse, mutect2, varscan2
- AL592490.1 | c.2599G>T p.E867* | Nonsense Mutation (SNP) | VAF 33/118 reads (28%) | catalogued as COSV69426739; called by muse, mutect2, varscan2
- AMPD1 | c.908A>G p.K303R | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV100815194; called by muse, mutect2, varscan2
- APC | c.1312+2T>A p.X438_splice | Splice Site (SNP) | VAF 93/109 reads (85%) | catalogued as CS058106, HS050002, COSV57403622, COSV99969803; called by muse, mutect2, varscan2
- ARHGAP20 | c.2966C>A p.S989Y | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV99505113; called by muse, mutect2, varscan2
- ATM | c.450_453del p.S151* | Frame Shift Del (DEL) | VAF 40/100 reads (40%) | catalogued as rs771936821; called by pindel, varscan2
- ATP8B3 | c.1696C>T p.R566C | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749622913, COSV59541965; called by muse, mutect2, varscan2
- BBS4 | c.13A>G p.R5G | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.007); catalogued as COSV99166526; called by muse, mutect2, varscan2
- BFAR | c.656C>A p.T219K | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.602); catalogued as COSV99902417; called by muse, mutect2, varscan2
- CABP4 | c.113C>T p.T38I | Missense Mutation (SNP) | VAF 13/16 reads (81%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as rs1158722137, COSV100351637; called by muse, mutect2, varscan2
- CEP135 | c.1746G>A p.M582I | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV99954810; called by muse, mutect2, varscan2
- CFAP91 | c.671C>T p.T224M | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as rs765608012, COSV99846789; called by muse, mutect2, varscan2
- COL4A1 | c.1996C>T p.R666* | Nonsense Mutation (SNP) | VAF 12/50 reads (24%) | catalogued as COSV101011091, COSV101011497; called by muse, mutect2, varscan2
- CR2 | c.2606G>A p.R869Q | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT tolerated (0.38); PolyPhen benign (0.188); catalogued as rs756989345, COSV100889697; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DCLK1 | c.643C>A p.Q215K | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV99712771; called by muse, mutect2, varscan2
- DNAI2 | c.865-1G>T p.X289_splice | Splice Site (SNP) | VAF 9/26 reads (35%) | catalogued as COSV100210028; called by muse, mutect2, varscan2
- DR1 | c.145C>A p.L49I | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as COSV100937842; called by muse, mutect2, varscan2
- ESM1 | c.449C>T p.T150M | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.65); catalogued as rs367904025; called by muse, mutect2, varscan2
- GALNT14 | c.728C>T p.S243L | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.311); catalogued as rs778348392, COSV61105848; called by muse, mutect2, varscan2
- GJC1 | c.342C>A p.S114R | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100395224; called by muse, mutect2, varscan2
- GRIA4 | c.1023G>T p.Q341H | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.47); PolyPhen benign (0.103); catalogued as COSV99234093; called by muse, mutect2, varscan2
- GRK4 | c.292C>T p.R98* (on ENST00000398052 / NM_182982.3; = p.R66* on NM_005307.3) | Nonsense Mutation (SNP) | VAF 24/54 reads (44%) | catalogued as rs1364672968, COSV61669918; called by muse, mutect2
- GTF3C4 | c.2129G>A p.R710H | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.854); catalogued as rs752487633, COSV64645428; called by muse, mutect2, varscan2
- HFM1 | c.2535-1G>T p.X845_splice | Splice Site (SNP) | VAF 70/165 reads (42%) | catalogued as COSV99646667; called by muse, mutect2, varscan2
- HS3ST3B1 | c.937G>T p.D313Y | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV62907345; called by muse, mutect2, varscan2
- IMPG2 | c.2301G>T p.K767N | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV99516319; called by muse, mutect2, varscan2
- ITGA5 | c.2921A>T p.Q974L | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV99516906; called by muse, mutect2, varscan2
- KCNH4 | c.1697G>A p.R566Q | Missense Mutation (SNP) | VAF 38/68 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99237801; called by muse, mutect2
- LDHD | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs771707660, COSV100097480; called by muse, mutect2, varscan2
- LPA | c.6073C>T p.R2025C | Missense Mutation (SNP) | VAF 104/269 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as rs765700553, COSV100307914; called by muse, mutect2, varscan2
- MAP1A | c.7258G>A p.G2420R | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as rs200292939; called by muse, mutect2, varscan2
- MAPK8IP1 | c.1781C>T p.A594V | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.842); catalogued as COSV99571726; called by muse, mutect2, varscan2
- MOGAT2 | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs754525542, COSV99549700; called by muse, mutect2, varscan2
- MYMK | c.135G>A p.A45= | Splice Region (SNP) | VAF 9/18 reads (50%) | catalogued as rs777300317, COSV101301172; called by muse, mutect2, varscan2
- OPRK1 | c.688G>A p.V230I | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.927); catalogued as rs186551684; called by muse, mutect2, varscan2
- OR10H3 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 58/131 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as rs1479729939, COSV100008471; called by muse, mutect2, varscan2
- OR1J2 | c.350C>A p.S117* | Nonsense Mutation (SNP) | VAF 59/143 reads (41%) | catalogued as COSV100093048, COSV100093377; called by muse, mutect2
- PCDH12 | c.854A>T p.K285M | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51519967, COSV99191294; called by muse, mutect2, varscan2
- PCDH15 | c.4574C>A p.P1525H (on ENST00000644397 / NM_001354429.2; = p.P1474H on NM_001142769.3) | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV64704778; called by muse, mutect2, varscan2
- PCDH15 | c.4880C>A p.T1627K | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.003); catalogued as COSV100226497, COSV57376391; called by muse, mutect2, varscan2
- PCDH9 | c.3679G>T p.G1227C (on ENST00000377865 / NM_203487.3; = p.G1193C on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as COSV100123005; called by muse, mutect2, varscan2
- PHF2 | c.1475del p.K492Rfs*6 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | catalogued as rs769717544; called by mutect2, varscan2
- PIK3CD | c.1715C>T p.P572L | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs756348630, COSV100740388, COSV100740473; called by muse, mutect2, varscan2
- PIK3R6 | c.2042G>A p.R681Q | Missense Mutation (SNP) | VAF 35/46 reads (76%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs372755765, COSV100266815; called by muse, mutect2, varscan2
- PLG | c.1256+1G>A p.X419_splice | Splice Site (SNP) | VAF 21/62 reads (34%) | catalogued as rs772727378, COSV51980986; called by muse, mutect2, varscan2
- PML | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); catalogued as COSV51448631; called by muse, mutect2, varscan2
- PPP2R3A | c.1718C>A p.T573K | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.086); catalogued as COSV99388027; called by muse, mutect2, varscan2
- PRPF8 | c.725C>G p.A242G | Missense Mutation (SNP) | VAF 32/38 reads (84%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100517836; called by muse, mutect2, varscan2
- PRRG3 | c.628G>A p.V210M | Missense Mutation (SNP) | VAF 53/56 reads (95%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as rs201939863, COSV64851210, COSV64851457; called by muse, mutect2, varscan2
- RGS14 | c.203T>A p.F68Y | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101281746; called by muse, mutect2, varscan2
- SCIN | c.1883T>C p.I628T (on ENST00000297029 / NM_001112706.3; = p.I381T on NM_033128.3) | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as rs755211011, COSV51694408; called by muse, mutect2, varscan2
- SPIRE2 | c.2035G>A p.V679M | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1343786860, COSV54529530; called by muse, mutect2, varscan2
- SRPX | c.793C>A p.L265I | Missense Mutation (SNP) | VAF 47/50 reads (94%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100656231; called by muse, mutect2, varscan2
- TECPR1 | c.1924G>A p.V642I | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs369859063; called by muse, mutect2, varscan2
- TLR8 | c.313G>A p.G105R (on ENST00000218032 / NM_138636.5; = p.G123R on NM_016610.4) | Missense Mutation (SNP) | VAF 84/89 reads (94%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs915691659, COSV54318438, COSV99028686; called by muse, mutect2, varscan2
- TPP1 | c.716A>G p.D239G | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100196968; called by muse, mutect2, varscan2
- TRUB2 | c.728G>C p.G243A | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100867917; called by muse, mutect2, varscan2
- TTYH1 | c.321C>G p.I107M | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV100002393; called by muse, mutect2, varscan2
- WNK2 | c.1094C>T p.A365V | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52940482; called by muse, mutect2, varscan2
- ZFP42 | c.694C>A p.L232I | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100479127; called by muse, mutect2, varscan2
- ZFP64 | c.1316C>T p.S439L | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.948); catalogued as rs1478015376, COSV99402961; called by muse, mutect2, varscan2
- ZNF19 | c.20A>T p.K7I | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.11); catalogued as COSV99867664; called by muse, mutect2, varscan2
- ZNF423 | c.1273C>T p.R425W (on ENST00000563137 / NM_001379286.1; = p.R417W on NM_015069.4) | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as rs772823132, COSV52197113; called by muse, mutect2, varscan2
- UBE2L3 | c.154_159del p.R52_I53del | In Frame Del (DEL) | VAF 57/168 reads (34%) | called by mutect2, pindel, varscan2
- C19orf44 | c.1969C>T p.L657= | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as COSV99550477; called by muse, mutect2, varscan2
- GGCX | c.477C>T p.N159= | Silent (SNP) | VAF 39/111 reads (35%) | catalogued as rs376855367; called by muse, mutect2, varscan2
- GUCY1A1 | c.1251A>G p.E417= | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as COSV99638455; called by muse, mutect2, varscan2
- HMHB1 | c.114T>A p.T38= | Silent (SNP) | VAF 66/172 reads (38%) | catalogued as rs754259879, COSV99193151; called by muse, mutect2, varscan2
- MDGA1 | c.2856G>A p.A952= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as rs757335830, COSV51792047; called by muse, mutect2, varscan2
- MED31 | c.114C>T p.A38= | Silent (SNP) | VAF 47/58 reads (81%) | catalogued as COSV99854626; called by muse, mutect2, varscan2
- PABPC1L | c.786C>T p.Y262= | Silent (SNP) | VAF 27/54 reads (50%) | catalogued as rs758644455, COSV99407730; called by muse, mutect2, varscan2
- PAPPA | c.1104G>A p.P368= | Silent (SNP) | VAF 11/20 reads (55%) | catalogued as rs1232382704, COSV60291676; called by muse, mutect2, varscan2
- PCDHA3 | c.2172C>T p.S724= | Silent (SNP) | VAF 39/94 reads (41%) | catalogued as rs140796793, COSV63543398; called by muse, mutect2, varscan2
- PGM3 | c.849T>A p.V283= | Silent (SNP) | VAF 31/74 reads (42%) | catalogued as COSV99392540; called by muse, mutect2, varscan2
- POMGNT2 | c.189C>T p.G63= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as rs377288837; called by muse, mutect2, varscan2
- SCN5A | c.5898C>A p.S1966= (on ENST00000333535 / NM_198056.3; = p.S1965= on NM_000335.5) | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as COSV100350227; called by muse, mutect2, varscan2
- SNX15 | c.447G>A p.P149= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as rs757575728, COSV57247049; called by muse, mutect2, varscan2
- SPAG1 | c.54C>T p.F18= | Silent (SNP) | VAF 53/165 reads (32%) | catalogued as COSV99309397; called by muse, mutect2, varscan2
- SYNDIG1 | c.333C>T p.C111= | Silent (SNP) | VAF 22/51 reads (43%) | catalogued as rs761476256, COSV65233336, COSV65236295; called by muse, mutect2, varscan2
- TSPOAP1 | c.3648C>T p.T1216= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs368307904; called by muse, mutect2, varscan2
- WDR91 | c.2193C>G p.A731= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV100615816; called by muse, mutect2, varscan2
- ZNF366 | c.510G>C p.L170= | Silent (SNP) | VAF 18/39 reads (46%) | catalogued as COSV100574423, COSV59218293; called by muse, mutect2, varscan2
- AP001267.5 | c.-799+5333del | Intron (DEL) | VAF 4/18 reads (22%) | called by pindel, varscan2
- GCNT2 | c.925+26841del | Intron (DEL) | VAF 12/54 reads (22%) | catalogued as rs1561796722; called by mutect2, pindel, varscan2
